Somatic mutation profile of tumor specimen 0DH3LI from CCDI case PBBTWL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.6 years (3,883 days).
Specimen 0DH3LI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) baf3ea3e-b515-4dee-8b2e-0ffe30fa45b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH3KC (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2fc69d5-a9ec-41ba-90c1-e7d338aa54d5

The open-access MAF lists 12 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Nonsense Mutation 2, Silent 1, Frame Shift Ins 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 253/714 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- BPIFB4 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 272/902 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.838); catalogued as rs577589403; called by muse, mutect2, varscan2
- HRH2 | c.1052C>T p.T351M | Missense Mutation (SNP) | VAF 193/684 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs201604970; called by muse, mutect2, varscan2
- MUC5AC | c.976C>T p.Q326* | Nonsense Mutation (SNP) | VAF 207/602 reads (34%) | catalogued as rs1019623184; called by muse, mutect2, varscan2
- ABCB11 | c.1083G>T p.Q361H | Missense Mutation (SNP) | VAF 143/521 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CCDC168 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 18/659 reads (3%) | called by muse, mutect2
- CYP2S1 | c.83C>A p.A28D | Missense Mutation (SNP) | VAF 127/364 reads (35%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- ECT2 | c.2559_2560insCTCTTTTTGGAGTTTTGGAGAAAGAGAAT p.A854Lfs*13 (on ENST00000392692 / NM_001349098.2; = p.A823Lfs*13 on NM_018098.6 and 2 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 19/1230 reads (2%) | called by muse*, mutect2
- HLTF | c.2692C>G p.Q898E | Missense Mutation (SNP) | VAF 56/1340 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2
- LRP2 | c.5883C>T p.S1961= | Silent (SNP) | VAF 157/599 reads (26%) | called by muse, varscan2
- OR5AN1 | chr11:59365493 C>T | 3'Flank (SNP) | VAF 36/161 reads (22%) | called by muse, mutect2, varscan2
- ST13 | c.578+11G>A | Intron (SNP) | VAF 22/515 reads (4%) | called by muse, mutect2
